Somatic mutation profile of tumor specimen TCGA-L4-A4E6-01A (aliquot TCGA-L4-A4E6-01A-11D-A24D-08) from TCGA case TCGA-L4-A4E6, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 67.4 years (24,631 days).
Specimen TCGA-L4-A4E6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 260fbe44-d0d3-4722-aa64-730c727e5dc1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L4-A4E6-10A (Blood Derived Normal), aliquot TCGA-L4-A4E6-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d00797fa-95bc-41a5-9687-de759bb98109

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1931G>T p.W644L (on ENST00000288602 / NM_001374244.1; = p.W604L on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV56131868, COSV56199774; called by muse, mutect2
- GPR173 | c.451T>C p.S151P | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100212394; called by muse, mutect2
- PCDHB11 | c.1606C>G p.R536G | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.052); catalogued as COSV100697126, COSV61311492, COSV61312515; called by muse, mutect2
- PPL | c.3868G>C p.E1290Q | Missense Mutation (SNP) | VAF 8/232 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV52165919; called by muse, mutect2
- GLB1L2 | c.918G>T p.V306= | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as COSV60278647, COSV60279097; called by muse, mutect2
- HOXA7 | c.414G>C p.T138= | Silent (SNP) | VAF 9/150 reads (6%) | catalogued as COSV99636560, COSV99636677, COSV99636867; called by muse, mutect2
- IL18RAP | c.1170G>T p.L390= | Silent (SNP) | VAF 11/261 reads (4%) | catalogued as COSV99962271, COSV99962460; called by muse, mutect2
- MAGEA6 | c.498G>C p.L166= | Silent (SNP) | VAF 8/120 reads (7%) | catalogued as COSV61449594; called by muse, mutect2
